Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A6E5, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A6E5-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT PELVIC LYMPH NODES:
Sixteen lymph nodes, no tumor present. (0/16)
(B) LEFT PELVIC LYMPH NODES:
Eleven lymph nodes, no tumor present. (0/11)
(C) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

Entire report and diagnosis completed by

path ICD-O-3
Adenocarcinoma NOS
8140/3
GCF Adenocarcinoma, acinar
8140/3
Site Prostate NOS
861.9
JW 5/21/13

GROSS DESCRIPTION

(A) RIGHT PELVIC LYMPH NODES – Multiple fragments of fatty tissue measuring in aggregate 7.0 x 4.5 x 1.5 cm. Dissection reveals multiple possible lymph nodes ranging from 0.3 up to 1.5 cm in greatest dimension. Possible lymph nodes are entirely submitted.

SECTION CODE: A1, four possible lymph nodes; A2, two possible lymph nodes; A3, two possible lymph nodes; A4, three possible lymph nodes; A5, one sectioned possible lymph node; A6, one sectioned possible lymph node; A7, one sectioned possible lymph node; A8, one sectioned possible lymph node; A9, one sectioned possible lymph node; A10, one sectioned possible lymph node; A11, A12, one sectioned possible lymph node.

(B) LEFT PELVIC LYMPH NODES – Multiple fragments of fatty tissue measuring in aggregate 7.5 x 5.0 x 1.5 cm. Dissection reveals multiple lymph nodes ranging from 0.5 up to 2.0 cm in greatest dimension. Possible lymph nodes are entirely submitted in cassettes.

SECTION CODE: B1, two possible lymph nodes; B2, one sectioned possible lymph node; B3, one sectioned possible lymph node; B4, one sectioned possible lymph node; B5, one sectioned possible lymph node; B6, one sectioned possible lymph node; B7, one sectioned possible lymph node; B8, one sectioned possible lymph node; B9, one sectioned possible lymph node; B10, B11, one sectioned possible lymph node.

(C) PROSTATE AND SEMINAL VESICLES – Supplemental report to follow.

CLINICAL HISTORY

Prostate cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

These tests have not been

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to add additional comments.

Addendum completed by

DIAGNOSIS

- (C) PROSTATE AND SEMINAL VESICLES:
PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (4+3) WITH TERTIARY GLEASON GRADE 5 COMPONENT.
TUMOR INVADING RIGHT SEMINAL VESICLE AND PERIVESICULAR SOFT TISSUE.
MARGINS OF RESECTION ARE FREE OF TUMOR.
PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE.
Left seminal vesicle and segment of left vas deferens, no tumor present.

COMMENT

The prostate gland contains four separate foci of prostatic adenocarcinoma, two in the peripheral zone and two in the transition zone. The dominant tumor focus is located in the right lateral, right posterolateral and right posterior peripheral zone. This tumor focus measures 2.0 x 1.0 cm in the largest cross-sectional dimension, and it is present in two cross sections and extensively in the apex and base regions. This tumor focus invades the right seminal vesicle, including intra and extraprostatic portions, and focally perivesicular soft tissue. The margins of resection are free of tumor. The second tumor focus is located in the left lateral, left posterolateral and left posterior peripheral zone. This tumor focus measures 1.5 x 0.4 cm in the largest cross-sectional dimension and it is present in two cross sections and focally in the apex and base regions. The third tumor focus is located in the right transition zone. This tumor focus measures 1.0 x 1.0 cm in the largest cross section dimension and it is present in two cross sections, extensively in the apex and focally in the base region. The fourth tumor focus is located in the left transition zone. This tumor focus measures 0.1 x less than 0.1 cm in the largest cross-sectional dimension and it is present in the first cross section of the prostate. The non-dominant tumor foci are lower histologic grade and confined to the prostate with negative margins.

GROSS DESCRIPTION

- (C) PROSTATE AND SEMINAL VESICLES - A prostate, attached right and left seminal vesicles and attached segments of right and left deferentia.

The prostate gland (4.7 x 3.3 x 4.0 cm, 33.0 gm, postfixation) has the usual shape. The soft tissue present along the right posterolateral aspect of the prostate appears more abundant than along the left side. Nodules are palpated on the right side of the prostate and left mid region. Serial cross sections after fixation demonstrate a firm area consistent with tumor in the right peripheral zone of the two cross sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: C1, C2, right seminal vesicle and segment of right vas deferens from the base towards the tip; C3, C4, left seminal vesicle and segment of left vas deferens from the base towards the tip; C5, prostatic base right border; C6-C10,

[page 3 of 3]
Specimen Date/Time:

prostatic base right posterior border; C11-C16, prostatic base central portion; C17, prostatic base left border; C18-C21, prostatic base left posterior border; C22-C24, apex anterior; C25, C26, apex left; C27, C28, apex posterior; C29, C30, apex right; C31, detached portions of margin of resection according to specimen radiograph; C32-C39, sections of the two cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Orange ink (C36) denotes surfaces that do not represent the true margin of resection.

SNOMED CODES

Entire report and diagnosis completed by:

-----END OF REPORT-----

Prx. Malignancy History		☒

Source: NCI Genomic Data Commons file 0c383d7c-4d4a-4080-93ac-160bf89f0d51 (TCGA-KK-A6E5.CB009865-4D04-4135-B3F1-5FB473029B12.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).